Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041119-09A.1 (aliquot TARGET-15-SJMPAL041119-09A.1-01D) from TARGET case TARGET-15-SJMPAL041119, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,105 days).
Specimen TARGET-15-SJMPAL041119-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a9cbd8a-01a1-45b2-8069-c96b7337bb3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041119-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041119-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1cd72ad-5d78-4331-a7a0-af1d053ba157

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 3, Nonsense Mutation 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 87/187 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C8A | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs755269006, COSV63485762; called by muse, mutect2, varscan2
- CD163L1 | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 112/207 reads (54%) | catalogued as COSV99047110; called by muse, mutect2, varscan2
- CDHR5 | c.2090G>A p.G697D (on ENST00000358353 / NM_001171968.2; = p.G703D on NM_021924.5) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs767827381; called by muse, mutect2, varscan2
- CNNM1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV63203328; called by muse, mutect2, varscan2
- DNMBP | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60619983; called by muse, mutect2, varscan2
- INTS1 | c.5399G>T p.R1800L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs1337007462; called by muse, mutect2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- NADSYN1 | c.2070+1G>A p.X690_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as rs1555152822; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 127/216 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- SREBF2 | c.1457T>C p.V486A | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104419536; called by muse, mutect2
- BCAR1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.514); called by muse, mutect2
- BTN2A1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- E4F1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PLPP6 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- SGPP2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STOX1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 152/298 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.15); called by muse, varscan2
- TTN | c.86406G>A p.W28802* (on ENST00000591111; = p.W21378* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/171 reads (25%) | called by muse, mutect2, varscan2
- TVP23A | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.017); called by muse, mutect2
- B4GALT7 | c.753G>A p.G251= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- COL6A2 | c.3030C>T p.F1010= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV52428384; called by muse, mutect2, varscan2
- FCGR2A | c.804C>T p.A268= (on ENST00000271450 / NM_001136219.3; = p.A267= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as rs1341662703; called by muse, mutect2, varscan2
- KCNJ16 | c.1230C>T p.N410= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs550235581; called by muse, mutect2
- KDELR1 | c.534C>T p.L178= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as COSV58102799; called by muse, varscan2
- SVEP1 | c.228G>A p.R76= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1188563743; called by muse, mutect2, varscan2
- ANK3 | c.12596-267G>T | Intron (SNP) | VAF 4/41 reads (10%) | catalogued as rs1050893490; called by muse, mutect2
- PARP1 | c.2407-19C>T | Intron (SNP) | VAF 98/221 reads (44%) | called by muse, mutect2, varscan2
- RAD21 | c.1704+48G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- TDRD3 | c.-121C>T | 5'UTR (SNP) | VAF 39/101 reads (39%) | catalogued as rs746076570; called by muse, mutect2, varscan2
